Surgical pathology report (de-identified scan), TCGA case TCGA-MP-A4T2, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Mayo Clinic, specimen TCGA-MP-A4T2-01A (Primary Tumor).

Surgical Pathology

Requested By:

TISSUE DESCRIPTION:

A1 B1 B2 C1 D1 E1
Tissue from left lower lobe lung (12.57 grams; 5 x 1.7 x 1.5 cm), superior (right lower paratracheal) and inferior (subcarinal) mediastinal lymph nodes

DIAGNOSIS:

Lung, left lower lobe, wedge excision: Invasive grade 3 (of 4) adenocarcinoma forming a peripheral 2.1 x 2 x 1 cm mass. The visceral pleura is not involved. The surgical margin of resection is negative for tumor.

Lymph nodes, superior (right lower paratracheal) and inferior (subcarinal) mediastinal, excision: Multiple superior (8 right lower paratracheal) and inferior (4 subcarinal) mediastinal lymph nodes are negative for tumor.

ICD - 0-3

Adenocarcinoma, NOS 8140/3

Site: lung, lower lobe C34.3

hw
10/27/12

Source: NCI Genomic Data Commons file 01422d49-aee5-4be9-b6d9-2b5bdd273213 (TCGA-MP-A4T2.EC30FFC5-3C51-49E7-8996-18D9BCFC8552.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).